Surgical pathology report (de-identified scan), TCGA case TCGA-24-0975, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Washington University, specimen TCGA-24-0975-01A (Primary Tumor).

[page 1 of 3]
Surgical Pathology Report

Final

SURGICAL PATHOLOGY REPORT

Physician(s):

Other Related Clinical Data:

DIAGNOSIS:

OMENTUM (FS1), OMENTECTOMY
- METASTATIC CARCINOMA

OMENTUM, OMENTECTOMY
- METASTATIC CARCINOMA

SOFT TISSUE, "PERITONEUM," EXCISION
- METASTATIC CARCINOMA

UTERUS, EXCISION
- METASTATIC CARCINOMA, SEROSA

- DETACHED FRAGMENTS OF SOFT TISSUE WITH METASTATIC CARCINOMA

- ENDOMETRIAL POLYP

- SEROSAL ENDOMETRIOSIS

OVARY, RIGHT, EXCISION
- ADENOCARCINOMA, MIXED PAPILLARY SEROUS AND ENDOMETRIOID TYPE, FIGO GRADE
III/III

FALLOPIAN TUBE, RIGHT, EXCISION
- METASTATIC CARCINOMA

OVARY, LEFT, EXCISION
- ADENOCARCINOMA, MIXED PAPILLARY SEROUS AND ENDOMETRIOID TYPE, FIGO GRADE
III/III

- ENDOMETRIOSIS

FALLOPIAN TUBE, LEFT, EXCISION
- METASTATIC CARCINOMA, SEROSAL SURFACE

By this signature, I attest that the above diagnosis is
based upon my personal
examination of the slides (and/or other material indicated in the
diagnosis).

***Report Electronically Reviewed and Signed Out By
Intraoperative Consultation:

An intraoperative non-microscopic consultation was obtained and interpreted as:

[page 2 of 3]
"Called to pick-up 'omentum' consisting of a 4.4 x 4.0 x 1.9 cm piece of fibrofatty tissue with extensive sclerotic white tumor involvement. Two pieces taken for FS1. Tumor taken for tumor bank. Rest for permanents," by FS1: Omentum, excision
- "Metastatic poorly differentiated carcinoma, favor Muellierian origin," by
Microscopic Description and Comment:
Microscopic examination substantiates the above cited diagnosis.

History:

The patient is a year old woman with recently diagnosed breast cancer and peritoneal carcinomatosis. CA125 level of 1460. Operative procedure: Examination under anesthesia, exploratory laparotomy, omentectomy, and debulking of tumor.

Specimen(s) Received:

- A: OMENTUM, ROUTINE
- B: OMENTUM, ROUTINE
- C: PERITONEUM
- D: TUMOR, UTERUS, CERVIX, BILATERAL ADNEXA

Gross Description

The specimens are received in four formalin-filled containers each labeled The first container is additionally labeled "omentum." It contains a white cassette labeled "FS1," that holds two yellow fragments of tissue, measuring 1.6 x 0.6 x 0.1 cm and 1.4 x 0.7 x 0.1 cm. Labeled A1. The container also holds two fragments of fibrofatty tissue measuring 4 x 3 x 1 cm and 3.5 x 3 x 0.6 cm. Both tissue fragments are lined by smooth white tissue. Labeled A2 and A3. Jar 1.
The second is additionally labeled "omentum." It contains several fibrofatty tissue fragments with gross infiltration by sclerotic tan-white tumor. The tissue fragments, range from 3 x 2 x 1 cm to 12 x 7 x 2 cm. Representative sections are taken are in B1 to B5. Jar 3.
The third container is additionally labeled "peritoneum." It contains a variegated brown fragment of tissue, measuring 3.5 x 1.5 x 0.7 cm. Labeled C1 and C2. Jar 0.
The fourth container is additionally labeled "tumor, uterus, cervix, bilateral adnexa." It contains a uterus weighing 77 grams and measuring 6.5 cm from fundus to ectocervix x 3.5 cm from cornu to cornu x 3 cm from anterior to posterior. The serosal surface is tan and smooth with multiple adhesions of friable variegated tan tissue. The right ovary is remarkable for the presence of multiple surface adhesions of variegated tan tissue. It measures 3 x 1.5 x 1 cm. On section, there is a firm white nodule measuring 0.8 x 0.6 x 0.5 cm. The unremarkable right fallopian tube measures 3.5 x 0.5 cm. The left ovary measures 2.5 x 1.5 x 1 cm and contains multiple surface adhesions of variegated tan tissue. On section, there is vague nodularity. The left fallopian tube measures 3.5 x 0.6 cm. The ectocervix of the uterus is tan and smooth. On section, the endocervical canal measures 2.5 cm in length. It is tan and smooth. The endometrial cavity is pink and smooth and measures 2.5 x 1.8 cm. A polypoid pink lesion is present in the anterior endometrial cavity, measuring 1.4 x 0.9 x 0.3 cm. Additionally present in the container are several variegated tan fragments of tissue, ranging from 0.7 x 0.2 x 0.1 cm to 2.5 x 1.5 x 0.7 cm. Labeled D1 - anterior cervix; D2 - anterior endometrium; D3 - posterior cervix; D4 - posterior lower uterine shavings; D5 - posterior endometrium; D6 and D7 - additional sections of anterior endometrium; D8 and D9

[page 3 of 3]
- additional sections of posterior endometrium; D10 to D12 - right ovary and fallopian tube; D13 and D15 - left ovary and fallopian tube; D16 to D18 - additional tissue in container. Jar 2.

SYNOPTIC REPORTING FORM FOR MALIGNANT OVARIAN NEOPLASMS

HISTOPATHOLOGIC TYPE

The histologic diagnosis is mixed papillary serous and endometrioid adenocarcinoma

TUMOR LOCATION

The locations of the primary tumor(s) are the right and left ovary (synchronous primary tumors)

HISTOLOGIC GRADE

The histologic grade is poorly differentiated (G3)

TUMOR INVASION

Tumor does invade the adjacent fallopian tube/peritubal soft tissue

TUMOR INVOLVEMENT

Metastatic involvement of the omentum is present

TUMOR SIZE

The maximum dimension of tumor implants outside the true pelvis is greater than or equal to 2 cm

PRIMARY TUMOR (T)

Based on the above information, the primary tumor is classified as macroscopic peritoneal metastasis beyond pelvis more than 2 cm in greatest dimension or regional lymph node metastasis (T3c/IIIC)

REGIONAL LYMPH NODES (N)

The regional lymph nodes cannot be assessed (NX)

DISTANT METASTASIS (M)

The status of distant tumor site cannot be assessed (MX)

STAGE GROUPING

The Final AJCC/UICC/FIGO stage is T3c/N0/M0 (Stage IIIC)

The pathologic stage assigned here should be regarded as provisional, and may change after integration of clinical data not provided with this specimen.

Source: NCI Genomic Data Commons file b4fa754e-bee8-4870-beaa-459a290d58cf (TCGA-24-0975.8AA65DCA-E057-486F-AEFA-D8A3485416EC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).